Somatic mutation profile of tumor specimen TCGA-H8-A6C1-01A (aliquot TCGA-H8-A6C1-01A-11D-A32N-08) from TCGA case TCGA-H8-A6C1, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 53.9 years (19,677 days).
Specimen TCGA-H8-A6C1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51ef46bf-c79b-4302-89e3-7050f31d8d93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H8-A6C1-10A (Blood Derived Normal), aliquot TCGA-H8-A6C1-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d9bdfde-3726-4ab9-afae-6dc37c4d2893

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL2 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99590578; called by muse, mutect2, varscan2
- ADGRL4 | c.1119G>A p.W373* | Nonsense Mutation (SNP) | VAF 48/316 reads (15%) | catalogued as COSV100876351, COSV66063786, COSV66064462; called by muse, mutect2, varscan2
- BMP2 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.938); catalogued as rs772329794, COSV66578937; called by muse, mutect2
- DENND4B | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100339268; called by muse, mutect2
- FCRLB | c.738C>A p.F246L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as COSV100396302; called by muse, mutect2, varscan2
- IFFO1 | c.1517G>A p.R506H (on ENST00000396840 / NM_001330324.2; = p.R509H on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/494 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144197395; called by muse, mutect2, varscan2
- ITIH5 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs761012253, COSV53661562; called by muse, mutect2, varscan2
- KAT6A | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as COSV99705622; called by muse, mutect2, varscan2
- LAMA2 | c.7681G>A p.G2561S | Missense Mutation (SNP) | VAF 107/527 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200341138, COSV70337235; called by muse, mutect2, varscan2
- MAN2B1 | c.2269C>T p.R757W | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs569187294, COSV99667194; called by muse, mutect2, varscan2
- MSC | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 368/1838 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs779458176, COSV57697499; called by muse, mutect2, varscan2
- NARS2 | c.985A>C p.I329L | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.151); catalogued as COSV99807438; called by muse, mutect2, varscan2
- NRP2 | c.1734G>A p.W578* | Nonsense Mutation (SNP) | VAF 62/267 reads (23%) | catalogued as COSV99785199; called by muse, mutect2, varscan2
- PCDH15 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV100225211; called by muse, mutect2, varscan2
- PROSER3 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99994653; called by muse, mutect2, varscan2
- RBFOX1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 185/875 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs761205127, COSV60956442; called by muse, mutect2, varscan2
- RIMS2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 102/510 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377666095; called by muse, mutect2, varscan2
- RNF213 | c.13013G>A p.R4338H | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60407456; called by muse, mutect2, varscan2
- SMC2 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs772638726, COSV53955371; called by muse, mutect2, varscan2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 45/266 reads (17%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- MAGEB6B | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 112/466 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PBK | c.50dup p.K18Efs*50 | Frame Shift Ins (INS) | VAF 24/101 reads (24%) | called by mutect2, varscan2
- FYB2 | c.1068T>G p.T356= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV100599696; called by muse, mutect2, varscan2
- MORC3 | c.2034A>T p.I678= | Silent (SNP) | VAF 45/259 reads (17%) | catalogued as COSV101265002, COSV68688780; called by muse, mutect2, varscan2
- PCDHA9 | c.471G>A p.A157= | Silent (SNP) | VAF 64/442 reads (14%) | catalogued as COSV65326296; called by muse, mutect2, varscan2
- SGSM1 | c.1749C>T p.C583= | Silent (SNP) | VAF 30/198 reads (15%) | catalogued as rs755987880, COSV101241000; called by muse, mutect2, varscan2
